Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A5UM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A5UM-01A (Primary Tumor).

Gross Description: There is a skin flap with black tumor on the broad base, up to 1.6 x 1.8 cm in size, 0.6 cm thick.

Microscopic Description: Malignant melanoma of the skin with superficial ulceration. Tumor Breslow thickness 5 mm.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.8 x 0.6 x 1.6 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Metastatic neoplasm, malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Breslow thickness 5 mm.

Comments: None

ICD O-3
Melanoma, malignant NOS
8720/3
Site: Skin of Trunk
C44.5
2/19/13

Site/Pathology Discrepancy		☒

Source: NCI Genomic Data Commons file 13553470-65d3-46fb-b686-0749bb5837c4 (TCGA-EB-A5UM.6CBB8671-BC4A-4986-9440-E12BED23DD38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).